TCGA case TCGA-DQ-7591 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Base of tongue; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ef779cf-772e-445e-93c8-e1094ea8b878

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C01; Tissue or organ of origin: Base of tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,798 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 69 days; Number of cycles: 1; Treatment dose: 664 mg; Prescribed dose: 83; Prescribed dose units: mg/wk; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 69 days; Number of cycles: 1; Treatment dose: 448 mg; Prescribed dose: 56; Prescribed dose units: mg/wk; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 70 days; Treatment dose: 7,000 cGy; Chemo concurrent to radiation: Yes; Course number: 1; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 70 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.

Follow-up (2 entries)
- Days to follow up: 360 days; Disease response: Tumor Free.
- Days to follow up: 622 days (1.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 3; Alcohol days per week: 3.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 1973.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DQ-7591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-DQ-7591-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 10.
- Sample TCGA-DQ-7591-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DQ-7591-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 3; Alcohol consumption frequency: 3.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Radiation treatment: Therapy regimen other: concurrent chemoradiation as definitive treatment.
- Follow-up form 1: New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 622 days; disease-specific survival: no event (censored), 622 days; progression-free interval: no event (censored), 622 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DQ-7591-01A-11D-2077-01): tumor purity 0.73, ploidy 1.95, whole-genome doublings 0.
